Somatic mutation profile of tumor specimen TARGET-20-PASSNX-09A (aliquot TARGET-20-PASSNX-09A-01D) from TARGET case TARGET-20-PASSNX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.5 years (5,312 days).
Specimen TARGET-20-PASSNX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1562da1-8dec-4abb-abdc-83ba00b12eb8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASSNX-14A (Bone Marrow Normal), aliquot TARGET-20-PASSNX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77eb60cc-3c2d-4875-b4a6-a7064ce0877e

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRXN1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.637); catalogued as COSV58434279; called by muse, mutect2, varscan2
- RELN | c.5095G>A p.E1699K | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs147657490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
